CCDI case PBBKGV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/da9dd53e-ee41-4ea9-a40a-35a0b760cc13

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 6.8 years (2,491 days).

Biospecimens (3 samples)
- Sample 0DAOEV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DAOS2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAOS3: Tissue type: Normal; Specimen type: Solid Tissue.
